Somatic mutation profile of tumor specimen TCGA-A2-A0CM-01A (aliquot TCGA-A2-A0CM-01A-31W-A050-09) from TCGA case TCGA-A2-A0CM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 41.0 years (14,969 days).
Specimen TCGA-A2-A0CM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 252f158f-9e24-4dcd-8989-8b59dba17f9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0CM-10A (Blood Derived Normal), aliquot TCGA-A2-A0CM-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/367b39e3-e42a-46af-b50b-db10d960fbc6

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 33, Silent 14, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs921477673, COSV65740290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1B3 | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 76/324 reads (23%) | catalogued as COSV53950279, COSV53950402; called by muse, mutect2, varscan2
- BMP4 | c.1011C>A p.C337* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV55416451; called by muse, mutect2, varscan2
- C12orf71 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV70282779; called by muse, mutect2, varscan2
- CCDC39 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 38/186 reads (20%) | catalogued as COSV56487464; called by muse, mutect2, varscan2
- CDH11 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51767655; called by muse, mutect2, varscan2
- CDKL2 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as rs753616785, COSV56734141; called by muse, mutect2, varscan2
- CYP27A1 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99298279; called by muse, mutect2
- DENND5A | c.3253T>C p.S1085P | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100063855; called by muse, mutect2, varscan2
- ELL2 | c.885G>C p.Q295H | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52983579; called by muse, mutect2, varscan2
- GIMAP2 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as COSV99785176; called by muse, mutect2
- GMPS | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV55810386; called by muse, mutect2, varscan2
- HPSE | c.10C>A p.R4S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV60987516; called by muse, mutect2
- IFNA2 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV66505720; called by muse, mutect2, varscan2
- IFT88 | c.767G>T p.R256I (on ENST00000319980 / NM_001318493.2; = p.R247I on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as rs1474573713, COSV60672929; called by muse, mutect2, varscan2
- INTU | c.824G>A p.R275K | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56538681, COSV99611351; called by muse, mutect2
- KAT6A | c.5324C>T p.P1775L | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV99704232; called by muse, mutect2
- KMO | c.1359G>C p.L453F | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV100086923; called by muse, mutect2
- MAGEC1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV53571941; called by muse, mutect2, varscan2
- NELFB | c.1507_1521del p.L503_D507del | In Frame Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs1329426985; called by mutect2, varscan2
- NHLH1 | c.321dup p.D108Rfs*8 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | catalogued as rs760805876; called by pindel, varscan2
- NIBAN3 | c.2051C>T p.S684F | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); catalogued as rs1166159915, COSV53110061; called by muse, mutect2, varscan2
- PIKFYVE | c.2459-2A>T p.X820_splice | Splice Site (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100009530; called by muse, mutect2
- PRSS35 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1157353385, COSV63800795; called by muse, mutect2, varscan2
- PRUNE1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV54958805; called by muse, mutect2, varscan2
- SLC28A3 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as COSV66152298, COSV66153954; called by muse, mutect2, varscan2
- SLTM | c.507A>T p.E169D | Missense Mutation (SNP) | VAF 88/159 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51055403; called by muse, mutect2, varscan2
- SPTA1 | c.6462G>T p.K2154N | Missense Mutation (SNP) | VAF 305/600 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV63755888; called by muse, mutect2, varscan2
- SYDE1 | c.1404C>G p.I468M | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54620698; called by muse, mutect2, varscan2
- SZT2 | c.8439G>C p.K2813N (on ENST00000634258 / NM_001365999.1; = p.K2756N on NM_015284.4) | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV65171309; called by muse, mutect2, varscan2
- TENM4 | c.5105G>A p.R1702H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs756075933, COSV53642633; called by muse, mutect2, varscan2
- THBS4 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63469976; called by muse, mutect2, varscan2
- TNN | c.2155G>C p.V719L | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53432620, COSV99510881; called by muse, mutect2
- TP53 | c.610del p.E204Sfs*43 | Frame Shift Del (DEL) | VAF 95/226 reads (42%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by mutect2, pindel, varscan2
- TTYH1 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100002270, COSV56612986; called by muse, mutect2, varscan2
- YY1AP1 | c.513G>C p.Q171H (on ENST00000295566 / NM_139118.2; = p.Q94H on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV55121061; called by muse, mutect2, varscan2
- ZCCHC2 | c.2704C>G p.L902V | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV54039325; called by muse, mutect2, varscan2
- ZNF22 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV53584304; called by muse, mutect2, varscan2
- ZNF689 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV54909343; called by muse, mutect2, varscan2
- ZNF77 | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV58821672, COSV58822222; called by muse, mutect2, varscan2
- AHCTF1 | c.3112del p.I1038Sfs*9 (on ENST00000366508; = p.I1012Sfs*9 on NM_015446.5) | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- PEG3 | c.3256G>A p.D1086N | Missense Mutation (SNP) | VAF 8/253 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- RPAP2 | c.1758_1774del p.L587Sfs*4 | Frame Shift Del (DEL) | VAF 49/312 reads (16%) | called by mutect2, pindel
- ANKLE2 | c.2364G>A p.R788= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs747751622, COSV100513896; called by muse, mutect2
- BICD1 | c.2775G>A p.Q925= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV55682190; called by muse, mutect2, varscan2
- CARD14 | c.1629C>T p.V543= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV60124714; called by muse, mutect2, varscan2
- CDC20B | c.552C>G p.L184= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as COSV57051624; called by muse, mutect2, varscan2
- CHD7 | c.1977C>A p.P659= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as COSV71112373; called by muse, mutect2, varscan2
- EXPH5 | c.5070G>A p.Q1690= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1287373545, COSV56204415; called by muse, mutect2, varscan2
- HFM1 | c.399C>T p.G133= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99645137; called by muse, mutect2
- IFT74 | c.81G>C p.G27= | Silent (SNP) | VAF 18/290 reads (6%) | catalogued as COSV101197113; called by muse, mutect2
- IRF8 | c.1206C>G p.V402= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV51898776; called by muse, mutect2, varscan2
- OR4C12 | c.597G>A p.V199= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV58860416; called by muse, mutect2, varscan2
- PAPPA | c.1173C>T p.I391= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV60278029; called by muse, mutect2
- PPP1R9A | c.2043A>G p.K681= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV56899153; called by muse, mutect2, varscan2
- SPIDR | c.1956G>T p.T652= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV52381430; called by muse, mutect2, varscan2
- TNN | c.2157G>A p.V719= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV99510883; called by muse, mutect2
